Somatic mutation profile of tumor specimen BA2515D (aliquot aq-BA2515D) from BEATAML1.0 case 2533, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with mutated CEBPA; Tissue or organ of origin: Bone marrow; Age at diagnosis: 74.6 years (27,233 days).
Specimen BA2515D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1a371b9f-9843-447c-ac6e-41980e9b183d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA3033D (Solid Tissue Normal), aliquot aq-BA3033D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3b499929-1d3e-4be0-ac40-1ce2bf14fecc

The open-access MAF lists 28 somatic variants for this specimen: 20 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 6, Nonsense Mutation 2, Splice Site 2, Intron 1, 5'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CEBPA | c.324C>G p.Y108* | Nonsense Mutation (SNP) | VAF 5/22 reads (23%) | catalogued as COSV57198636; called by muse, varscan2
- PAM | c.691G>A p.V231I | Missense Mutation (SNP) | VAF 13/210 reads (6%) | SIFT tolerated (0.51); PolyPhen benign (0.087); catalogued as COSV57216658; called by muse, mutect2
- PTMA | c.76G>T p.E26* | Nonsense Mutation (SNP) | VAF 24/216 reads (11%) | catalogued as COSV58186853; called by muse, mutect2, varscan2
- PUF60 | c.616A>C p.S206R (on ENST00000526683 / NM_001362896.2; = p.S189R on NM_014281.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as rs1186198160; called by muse, mutect2, varscan2
- SBNO2 | c.2858G>A p.R953Q | Missense Mutation (SNP) | VAF 39/132 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.877); catalogued as rs759411667, COSV62322211; called by muse, mutect2, varscan2
- SMC3 | c.2535+1G>A p.X845_splice | Splice Site (SNP) | VAF 27/116 reads (23%) | catalogued as COSV62420100; called by mutect2, varscan2
- SRRM3 | c.353G>A p.R118Q | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.386); catalogued as rs782140656, COSV58388156; called by muse, mutect2, varscan2
- SYNE1 | c.4088A>G p.H1363R (on ENST00000367255 / NM_182961.4; = p.H1370R on NM_033071.3) | Missense Mutation (SNP) | VAF 68/454 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.177); catalogued as rs780211468; called by muse, mutect2, varscan2
- TET2 | c.3473C>T p.A1158V | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV54402626; called by muse, mutect2, varscan2
- ZMIZ1 | c.901G>A p.A301T | Missense Mutation (SNP) | VAF 27/137 reads (20%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.824); catalogued as COSV57892061; called by muse, mutect2, varscan2
- DPF2 | c.883T>A p.C295S | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LGR5 | c.2198A>G p.N733S | Missense Mutation (SNP) | VAF 20/193 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PPP1R16A | c.1006C>A p.R336S | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.96); PolyPhen benign (0.006); called by muse, mutect2
- PTOV1 | c.872A>G p.E291G | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2
- RHOBTB1 | c.1718C>T p.A573V | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.689); called by muse, mutect2, varscan2
- SELENOS | c.210G>T p.V70= | Splice Region (SNP) | VAF 4/52 reads (8%) | called by muse, mutect2
- SHOC1 | c.1952A>G p.E651G | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.797); called by muse, varscan2
- SLC6A2 | c.1590+1G>C p.X530_splice | Splice Site (SNP) | VAF 8/191 reads (4%) | called by muse, mutect2
- TRIM3 | c.1714G>A p.A572T | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.013); called by mutect2, varscan2
- TTN | c.78647C>T p.P26216L (on ENST00000591111; = p.P18792L on NM_003319.4) | Missense Mutation (SNP) | VAF 12/112 reads (11%) | PolyPhen benign (0.242); called by muse, mutect2
- ADAL | c.528C>A p.G176= | Silent (SNP) | VAF 8/180 reads (4%) | called by muse, mutect2
- BAIAP3 | c.978C>A p.V326= | Silent (SNP) | VAF 4/52 reads (8%) | called by muse, mutect2
- EHBP1L1 | c.3225C>A p.I1075= | Silent (SNP) | VAF 3/19 reads (16%) | called by muse, mutect2
- PPP1R12B | c.522G>T p.L174= | Silent (SNP) | VAF 16/147 reads (11%) | called by muse, mutect2, varscan2
- TNFRSF10B | c.864A>G p.E288= | Silent (SNP) | VAF 10/361 reads (3%) | catalogued as COSV52391344; called by muse, mutect2
- TRPM2 | c.3528G>A p.R1176= | Silent (SNP) | VAF 15/131 reads (11%) | called by muse, mutect2
- ARPP21 | c.1644+863G>A | Intron (SNP) | VAF 17/77 reads (22%) | catalogued as rs184147157; called by muse, mutect2, varscan2
- RERG | c.-17G>T | 5'UTR (SNP) | VAF 23/136 reads (17%) | called by muse, varscan2
